Surgical pathology report (de-identified scan), TCGA case TCGA-23-1123, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1123-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

PATIENT:

Hospital No.:

Date of Birth:

Soc. Sec. No.:

Location:

Pathologist:

Assistant:

Attending MD:

Ordering MD:

Copies To:

=====

DIAGNOSIS:

1. PELVIC ADHESIONS, EXCISION:
- Predominantly mature adipose tissue
- One lymph node with reactive follicular hyperplasia
- Negative for malignancy
- 2,3,4. OMENTUM, 1,2,3, PARTIAL OMENTECTOMY:
- Predominantly mature adipose omental tissue
- Focal reactive mesothelial cells
- Occasional multinucleated foreign-body giant cells
- Negative for malignancy
5. OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY:
- High grade mullerian-derived adenocarcinoma (papillary serous type) involving the ovary and paratubal soft tissue, but the fallopian tube is not directly involved
- Paratubal benign mullerian-derived cyst
6. OVARY AND FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY:
- High grade mullerian-derived adenocarcinoma, replacing the ovary and infiltrating paratubal soft tissue
7. PERIURETERAL TISSUE, BIOPSY:
- High-grade mullerian-derived adenocarcinoma, metastatic
8. OVARIAN TUMOR, FROZEN SECTION NUMBER 1:
- High grade mullerian-derived adenocarcinoma
9. LYMPH NODE, FROZEN SECTION NUMBER 2:
- Metastatic high grade mullerian-derived adenocarcinoma
10. OVARIAN TUMOR, EXCISION:
- High grade mullerian-derived adenocarcinoma with extensive necrosis

=====

HISTORY: Possible ovarian carcinoma

MICROSCOPIC:

See Diagnosis.

GROSS:

1: PELVIC ADHESIONS

Labeled "pelvic adhesions" and received in formalin is a 2.0 x 1.5 x 0.7 cm portion of tan-yellow lobulated fat with a small amount of

[page 2 of 2]
Labeled "periureteral biopsy" and received in formalin is a 1.8 x 1.33 x 1.2 cm lobulated tan fragment of tumor.

N. All embedded - Multiple

8: FROZEN SECTION NO.1

Labeled "frozen section No.1", received fresh in the Operating Room, utilized for frozen section intraoperative diagnosis and subsequently fixed in formalin, is a 2.0 x 1.5 x 0.2 cm tan friable tissue fragment. All embedded.

O. Frozen section remnant of FS No.1 - 1

9: FROZEN SECTION NO.2 (LYMPH NODE)

Labeled "frozen section No.2 plus remnant", received fresh in the Operating Room, utilized for frozen section intraoperative diagnosis and subsequently fixed in formalin, is a 1.5 x 1.5 x 0.7 cm firm tan lymph node. A piece is frozen for intraoperative diagnosis. The remaining tissue is fixed in formalin. Representative sections are submitted.

P. Frozen section remnant of FS No.2 - 1

Q. Additional tissue - 2

10: OVARIAN TUMOR

Labeled "ovarian tumor" and received in formalin is a 2.5 x 2.0 x 1.5 cm aggregate of soft brown, congested, grossly necrotic tissue.

R. Representative sections - Multiple

[REDACTED]

OPERATIVE CONSULT (FROZEN):

#1: High-grade malignant tumor

#2: Lymph node with metastatic carcinoma

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 911931e2-0870-466d-ad2a-5496a766ceb8 (TCGA-23-1123.28F9189B-24EB-4540-8551-4EAACC296C20.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).